Somatic mutation profile of tumor specimen TCGA-VQ-A94R-01A (aliquot TCGA-VQ-A94R-01A-11D-A410-08) from TCGA case TCGA-VQ-A94R, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 63.6 years (23,246 days).
Specimen TCGA-VQ-A94R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfc137b8-595b-4deb-8b1f-2752c337b21b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A94R-10A (Blood Derived Normal), aliquot TCGA-VQ-A94R-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6af15906-7d5d-4bce-b167-c2458e111c75

The open-access MAF lists 325 somatic variants for this specimen: 244 protein-altering or splice-affecting, 78 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 78, Nonsense Mutation 10, In Frame Del 5, Frame Shift Del 4, Splice Region 3, Frame Shift Ins 3, Splice Site 2, 3'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- SCN1A | c.3734G>A p.R1245Q (on ENST00000303395 / NM_001202435.3; = p.R1234Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs121917912, CM067003, COSV57689039; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+2T>C p.X331_splice | Splice Site (SNP) | VAF 24/39 reads (62%) | hotspot (GDC flag); catalogued as COSV52703680, COSV52798259, COSV52814192; called by muse, mutect2, varscan2
- A2M | c.2633A>G p.E878G | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100588966, COSV59387635; called by muse, mutect2, varscan2
- A2M | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV59388845; called by muse, mutect2, varscan2
- A2ML1 | c.4202T>G p.L1401R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100229332; called by muse, mutect2, varscan2
- ABCA12 | c.4580C>T p.A1527V (on ENST00000272895 / NM_173076.3; = p.A1209V on NM_015657.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1429840331, COSV99791759; called by muse, mutect2, varscan2
- ABCA12 | c.3598T>G p.L1200V (on ENST00000272895 / NM_173076.3; = p.L882V on NM_015657.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV99791760; called by muse, mutect2, varscan2
- ABCC3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99559736; called by muse, mutect2, varscan2
- ABI3BP | c.509T>G p.I170S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV99428388; called by muse, mutect2, varscan2
- ACAN | c.4308A>T p.E1436D | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.914); catalogued as COSV100719160; called by muse, varscan2
- ADAMTS12 | c.2988C>A p.C996* | Nonsense Mutation (SNP) | VAF 45/168 reads (27%) | catalogued as COSV100711609; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs766086000, COSV100416909; called by muse, mutect2
- ADGRF4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs547273598, COSV99348907; called by muse, mutect2, varscan2
- AHNAK2 | c.12949A>C p.I4317L | Missense Mutation (SNP) | VAF 151/538 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.084); catalogued as COSV100318822; called by muse, mutect2, varscan2
- AIM2 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); catalogued as COSV100931140, COSV63699717; called by muse, mutect2, varscan2
- AKAP5 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100277990; called by muse, mutect2, varscan2
- AKAP9 | c.6955G>A p.D2319N (on ENST00000359028; = p.D2295N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as rs1554449451, COSV100663019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1B1 | c.559T>G p.F187V | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1563914891, COSV100890993; called by muse, mutect2, varscan2
- ANKRD12 | c.5157A>C p.E1719D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100042009; called by muse, mutect2, varscan2
- AP002512.3 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV54407336; called by muse, mutect2
- APC2 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs558896411, COSV99279818; called by muse, varscan2
- ARHGAP12 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100260848; called by muse, mutect2, varscan2
- ARPP21 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766212549, COSV99493170; called by muse, mutect2, varscan2
- ART1 | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV99167248; called by muse, varscan2
- AXDND1 | c.2134T>G p.L712V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV100858615; called by muse, mutect2, varscan2
- BCHE | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as rs1198996365, COSV100012939; called by muse, mutect2, varscan2
- BCORL1 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99500783; called by muse, mutect2, varscan2
- C10orf62 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV101035325; called by muse, mutect2, varscan2
- C10orf71 | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV60505765, COSV60514747; called by muse, mutect2, varscan2
- C1R | c.896T>A p.L299Q (on ENST00000536053 / NM_001354346.2; = p.L285Q on NM_001733.7) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101599229; called by muse, mutect2
- CACNA1E | c.4645A>G p.T1549A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100704998; called by muse, mutect2, varscan2
- CAPN13 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV99701016; called by muse, mutect2, varscan2
- CASKIN2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100050892; called by muse, mutect2, varscan2
- CCBE1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1426513179, COSV101232862; called by muse, mutect2, varscan2
- CCDC8 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs758816408, COSV100282155; called by muse, mutect2, varscan2
- CD163L1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as COSV100550611; called by muse, mutect2, varscan2
- CDC14A | c.713C>G p.T238R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100325886; called by muse, mutect2, varscan2
- CDH10 | c.2187del p.Y730Tfs*19 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as rs1273877423; called by mutect2, pindel, varscan2
- CDH12 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV101203283; called by muse, mutect2, varscan2
- CDH24 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as rs1244911981, COSV57460165; called by muse, mutect2, varscan2
- CDH4 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1410537320, COSV64668347; called by muse, mutect2, varscan2
- CEACAM1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs775600985, COSV99362585; called by muse, mutect2, varscan2
- CENPJ | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV101121573; called by muse, mutect2, varscan2
- CEP170 | c.2954G>C p.R985T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100316612, COSV100317759, COSV60509960; called by muse, mutect2, varscan2
- CEP250 | c.5086G>A p.G1696S | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV100699166; called by muse, mutect2, varscan2
- CFAP126 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs753086835, COSV100713769; called by muse, mutect2, varscan2
- CHD6 | c.6531C>G p.H2177Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.637); catalogued as COSV100951332; called by muse, mutect2, varscan2
- CHI3L2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs757716048, COSV63874352; called by muse, mutect2, varscan2
- CHI3L2 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869317, COSV100869323; called by muse, mutect2, varscan2
- CHN1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373546784; called by muse, mutect2, varscan2
- CHRNA6 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs373928428; called by muse, mutect2, varscan2
- CHRNB2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100872669; called by muse, mutect2, varscan2
- CNTN6 | c.3065T>G p.F1022C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100611778; called by muse, mutect2, varscan2
- COL5A2 | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880733; called by muse, mutect2, varscan2
- COLGALT1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs201380344, COSV99395266; called by muse, mutect2, varscan2
- CORIN | c.2562G>C p.W854C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56698510, COSV99904374; called by muse, mutect2
- CPA3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs772998748, COSV99936443; called by muse, mutect2, varscan2
- CPNE1 | c.1444C>T p.Q482* (on ENST00000352393; = p.Q487* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV100468028; called by muse, mutect2, varscan2
- CPNE2 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99321583; called by muse, mutect2, varscan2
- CROT | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV100519668; called by muse, mutect2, varscan2
- CSMD1 | c.8942A>C p.N2981T (on ENST00000520002; = p.N2980T on NM_033225.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100153162; called by muse, mutect2, varscan2
- CTCF | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs747052464, COSV50480149; called by muse, varscan2
- CYP11B2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as rs1392243160, COSV100011341; called by mutect2, varscan2
- DAAM1 | c.2238A>T p.E746D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV100658642; called by muse, mutect2, varscan2
- DAB2IP | c.2393C>G p.A798G (on ENST00000408936; = p.A770G on NM_032552.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.396); catalogued as COSV99406262; called by muse, mutect2, varscan2
- DNAH17 | c.10577G>A p.R3526H | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs372114864; called by muse, mutect2, varscan2
- DPEP3 | c.357T>A p.N119K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV99262867; called by muse, mutect2, varscan2
- EP400 | c.9362C>T p.P3121L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs779770506, COSV100202144; called by muse, mutect2, varscan2
- EPPK1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150196045; called by muse, mutect2, varscan2
- ERG28 | c.352A>C p.I118L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99471538; called by muse, mutect2
- ETAA1 | c.1156T>G p.L386V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99712918; called by muse, mutect2, varscan2
- FCRL4 | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV54865644, COSV99620377; called by muse, mutect2, varscan2
- FERMT3 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777040462, COSV99656781; called by muse, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | catalogued as rs755527396; called by mutect2, varscan2
- FLG | c.4615A>G p.S1539G | Missense Mutation (SNP) | VAF 149/367 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100912077, COSV64237938; called by muse, mutect2, varscan2
- FLNC | c.6199C>G p.R2067G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754160175, COSV100368674, COSV57960471; called by muse, mutect2, varscan2
- FRAS1 | c.4045A>G p.T1349A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs1251887388, COSV99355511; called by mutect2, varscan2
- FRMD1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs767006393, COSV51960716; called by muse, mutect2, varscan2
- FRY | c.3846G>A p.Q1282= | Splice Region (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100969859; called by muse, mutect2, varscan2
- GABRG1 | c.1127C>A p.A376D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs200059897, COSV99778667; called by muse, mutect2, varscan2
- GEN1 | c.1441C>G p.P481A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs374176559, COSV100438184; called by muse, mutect2, varscan2
- GJA10 | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs761449449, COSV101005436; called by muse, mutect2
- GOLGA6A | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1232556198; called by muse, mutect2, varscan2
- GOLM1 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV99974501; called by muse, mutect2, varscan2
- GRIK1 | c.2822G>A p.R941Q (on ENST00000327783 / NM_001330994.2; = p.R897Q on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs748380852, COSV100583163; called by muse, mutect2, varscan2
- H2AC12 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as rs146351262; called by muse, mutect2, varscan2
- H4C12 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs772156373, COSV62743962; called by muse, mutect2, varscan2
- HCST | c.108A>C p.S36= | Splice Region (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99385726, COSV99385738; called by muse, mutect2, varscan2
- HECTD4 | c.12407C>T p.P4136L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1566057724, COSV66390035; called by muse, mutect2, varscan2
- HECTD4 | c.10058A>T p.H3353L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101108344; called by muse, mutect2, varscan2
- HECTD4 | c.5846T>C p.L1949P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101108345; called by muse, mutect2, varscan2
- HECTD4 | c.4888G>A p.V1630I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs759425154, COSV66396102; called by muse, mutect2, varscan2
- HMCN1 | c.16792C>T p.R5598* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs193921043, COSV54900490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS6ST2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as rs1343237295, COSV100897424; called by muse, mutect2, varscan2
- HSF5 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs547910825, COSV100090734; called by muse, mutect2, varscan2
- HSPA6 | c.1051T>G p.L351V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV100554302, COSV59062758; called by muse, mutect2, varscan2
- HTR1A | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109259; called by muse, mutect2, varscan2
- IGSF9 | c.1849C>T p.P617S (on ENST00000368094 / NM_001135050.2; = p.P601S on NM_020789.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100829657; called by muse, mutect2, varscan2
- IGSF9B | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs201162330, COSV58067726; called by muse, mutect2, varscan2
- IL4R | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs145473866; called by muse, mutect2, varscan2
- INTS14 | c.707T>A p.V236E (on ENST00000313182 / NM_001366360.2; = p.V157E on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV100500093; called by muse, mutect2, varscan2
- KCNA4 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs747595084, COSV60251264; called by muse, mutect2, varscan2
- KCNA7 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537027580, COSV55502753; called by muse, mutect2, varscan2
- KCNB2 | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101579045, COSV73049565; called by muse, mutect2, varscan2
- KCND2 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58596156; called by muse, mutect2, varscan2
- KCNG4 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs774022999, COSV57586621; called by muse, mutect2, varscan2
- KDM6B | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV99642201; called by muse, mutect2, varscan2
- KIAA1549L | c.2551G>A p.A851T (on ENST00000321505; = p.A1148T on NM_012194.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs776240568, COSV55774468; called by muse, mutect2, varscan2
- KIF20A | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV99137591; called by muse, mutect2, varscan2
- KLHL32 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100987481; called by muse, mutect2, varscan2
- KRTAP27-1 | c.37C>A p.H13N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.083); catalogued as COSV101239778; called by muse, mutect2, varscan2
- KSR1 | c.2439C>A p.S813R (on ENST00000644974 / NM_001367810.1; = p.S698R on NM_014238.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52037029, COSV99260717; called by muse, mutect2, varscan2
- LAMA1 | c.3721G>A p.V1241M | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs763867369, COSV101056535; called by muse, mutect2, varscan2
- LCP2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50449677; called by muse, mutect2
- LHX9 | c.174G>A p.A58= | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100436060; called by muse, mutect2, varscan2
- LILRA1 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1444110384, COSV99252114; called by muse, varscan2
- LIN54 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); catalogued as COSV100464971; called by muse, mutect2, varscan2
- LIPF | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150812830; called by muse, mutect2, varscan2
- LPIN1 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV99878136; called by muse, mutect2
- LRBA | c.6559A>G p.T2187A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756885055, COSV100842049; called by muse, mutect2, varscan2
- LRP4 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101066439; called by muse, mutect2, varscan2
- LYPD6B | c.463G>A p.V155I (on ENST00000409029 / NM_001317004.1; = p.V179I on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs373317284; called by muse, mutect2, varscan2
- MAGEC1 | c.1838A>C p.Q613P | Missense Mutation (SNP) | VAF 79/120 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV99596440; called by muse, mutect2, varscan2
- MAGI3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100290289; called by muse, mutect2
- MAGI3 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.244); catalogued as rs61751950, COSV100290296; called by mutect2, varscan2
- MAN2A2 | c.3007C>T p.H1003Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100847982; called by muse, mutect2, varscan2
- MAN2B2 | c.985T>G p.F329V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99577987; called by muse, mutect2, varscan2
- MAN2B2 | c.2999G>C p.R1000P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53450411, COSV99577991; called by muse, mutect2, varscan2
- MAPK1 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.939); catalogued as COSV99308183; called by muse, mutect2, varscan2
- MATR3 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV100735320; called by muse, mutect2, varscan2
- MBD5 | c.3396C>G p.D1132E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.062); catalogued as COSV101290252; called by muse, mutect2, varscan2
- MED4 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99320066; called by muse, mutect2
- MFSD6 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855376; called by muse, mutect2, varscan2
- MMP16 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV54181143, COSV99690205; called by muse, mutect2, varscan2
- MMP9 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs1292338609, COSV100812455; called by muse, mutect2, varscan2
- MORN4 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100167431; called by muse, mutect2, varscan2
- MRPL2 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs756727490, COSV52440445; called by muse, mutect2, varscan2
- MTFMT | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584504; called by muse, mutect2, varscan2
- MTUS2 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs576095515, COSV70916361; called by muse, mutect2, varscan2
- MUC17 | c.583A>C p.S195R | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100074915; called by muse, mutect2, varscan2
- MYD88 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100086423; called by muse, mutect2, varscan2
- NCF2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV100838941; called by muse, mutect2, varscan2
- NLRP9 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV60459177; called by muse, mutect2, varscan2
- NRGN | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99423470; called by muse, mutect2, varscan2
- NRXN3 | c.704G>C p.G235A (on ENST00000557594 / NM_001272020.2; = p.G867A on NM_004796.6) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99821508; called by muse, mutect2, varscan2
- OBSCN | c.8167G>A p.E2723K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.734); catalogued as rs769975167, COSV99483773; called by muse, mutect2, varscan2
- OR56A3 | c.292T>G p.F98V | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100290363; called by muse, mutect2, varscan2
- OR5A2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs267603038, COSV57390771; called by muse, mutect2, varscan2
- OR5M3 | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100392680; called by muse, mutect2, varscan2
- OR9G4 | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV100265253; called by muse, mutect2, varscan2
- OVCH1 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs531573487, COSV100549153; called by muse, mutect2, varscan2
- PARP14 | c.3383C>T p.A1128V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV101506341; called by muse, mutect2
- PAX1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV68272398; called by muse, mutect2, varscan2
- PCDHA8 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100970033; called by muse, mutect2, varscan2
- PITPNM3 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99339005; called by muse, mutect2, varscan2
- PLEKHG1 | c.3559G>A p.V1187I | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368937253; called by muse, mutect2, varscan2
- PLVAP | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV99391815; called by muse, mutect2, varscan2
- PNPLA1 | c.1435C>T p.H479Y (on ENST00000394571 / NM_001374623.1; = p.H384Y on NM_173676.2) | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.029); catalogued as COSV100463619; called by muse, mutect2, varscan2
- PRPF4 | c.1097G>A p.G366D (on ENST00000374198 / NM_001322267.2; = p.G367D on NM_004697.5) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs571647333, COSV100950756; called by muse, mutect2, varscan2
- RAPGEF4 | c.1125G>C p.E375D | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99911540; called by muse, mutect2
- REV3L | c.8902C>T p.R2968C | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs140606020; called by muse, mutect2, varscan2
- REV3L | c.2971C>A p.L991I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100725659; called by muse, mutect2, varscan2
- RICTOR | c.1300-2A>T p.X434_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99705663; called by muse, mutect2, varscan2
- RIMS1 | c.623A>T p.K208M | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53471566, COSV99330109; called by muse, mutect2
- RIMS2 | c.4666T>A p.F1556I (on ENST00000666250 / NM_001348490.2; = p.F1127I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99194629; called by muse, mutect2, varscan2
- RNF165 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs752024290, COSV99491740; called by muse, mutect2, varscan2
- RPL10 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.816); catalogued as COSV99186288; called by muse, mutect2, varscan2
- RYR2 | c.9358G>A p.D3120N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100772616; called by muse, mutect2, varscan2
- SAMD1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV99513954; called by muse, mutect2, varscan2
- SCN10A | c.5327G>C p.R1776T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV101479520; called by muse, mutect2, varscan2
- SCN10A | c.119A>C p.K40T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV101479521; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SCUBE2 | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 88/127 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0.341); catalogued as COSV100496908; called by muse, mutect2, varscan2
- SETD3 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1262522785, COSV100075431; called by muse, mutect2, varscan2
- SFMBT2 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1164281001, COSV100739597; called by muse, mutect2, varscan2
- SFRP4 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99554652; called by muse, mutect2, varscan2
- SIGLEC6 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.603); catalogued as COSV100585658; called by muse, mutect2, varscan2
- SIGLEC6 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.472); catalogued as COSV100585660; called by muse, mutect2, varscan2
- SIPA1L2 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99479540; called by muse, mutect2
- SLC17A7 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs1267098779, COSV55549637; called by muse, mutect2, varscan2
- SLC22A16 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770486939, COSV100397912, COSV57930048; called by muse, mutect2
- SLC32A1 | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54148107, COSV99462612; called by muse, mutect2, varscan2
- SLC35A1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758449449, COSV101060077; called by muse, mutect2, varscan2
- SLC6A19 | c.830_832del p.F277del | In Frame Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs1465576975; called by pindel, varscan2
- SLCO6A1 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101134923; called by muse, mutect2, varscan2
- SLIT3 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV60637899; called by muse, mutect2, varscan2
- SMG1 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1394185717, COSV101246753; called by muse, mutect2, varscan2
- SNAP47 | c.330C>G p.F110L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100248452; called by muse, mutect2, varscan2
- SNX5 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 41/534 reads (8%) | catalogued as COSV100899081; called by muse, mutect2
- SPPL3 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100793764; called by muse, mutect2, varscan2
- STXBP4 | c.173G>C p.C58S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100178390; called by muse, mutect2, varscan2
- SUPT20H | c.376G>A p.D126N (on ENST00000350612 / NM_001014286.3; = p.D127N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV62248066; called by muse, mutect2, varscan2
- SUV39H2 | c.350A>G p.K117R (on ENST00000354919 / NM_001193424.2; = p.K57R on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1436796456, COSV100543182; called by muse, mutect2, varscan2
- SYNGAP1 | c.2645G>C p.G882A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99538945; called by muse, mutect2
- TAF1L | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs757557186, COSV54258123; called by muse, mutect2, varscan2
- TAS1R2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs138972387, COSV64743801; called by muse, mutect2, varscan2
- TASOR2 | c.2479A>C p.N827H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100050964; called by muse, mutect2, varscan2
- TBX18 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.304); catalogued as COSV63736869; called by muse, mutect2, varscan2
- TBX5 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100092044; called by muse, mutect2, varscan2
- TCF23 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.763); catalogued as COSV99940271, COSV99940412; called by muse, mutect2, varscan2
- TCTN3 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.343); catalogued as COSV99797530; called by muse, mutect2, varscan2
- TET3 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.088); catalogued as COSV99996586; called by muse, mutect2, varscan2
- THNSL1 | c.2049A>C p.E683D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100896300; called by muse, mutect2, varscan2
- TMEM132D | c.2591A>C p.K864T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV67160504, COSV67160536; called by muse, mutect2, varscan2
- TMEM170A | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1027118685, COSV100713282; called by muse, varscan2
- TMEM184C | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99669792; called by muse, varscan2
- TMOD2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); catalogued as rs1316085724, COSV99988030; called by muse, mutect2, varscan2
- TMTC4 | c.159T>G p.N53K (on ENST00000376234 / NM_001350577.2; = p.N72K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168868; called by muse, mutect2, varscan2
- TNPO1 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100473923; called by muse, mutect2, varscan2
- TRABD | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100326946; called by muse, mutect2, varscan2
- TRPV6 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 33/40 reads (83%) | catalogued as COSV100844419; called by muse, mutect2, varscan2
- TTBK2 | c.2176A>C p.S726R | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV51167463, COSV51169539; called by muse, mutect2, varscan2
- TTLL7 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.242); catalogued as rs1302819735, COSV53081881; called by muse, mutect2, varscan2
- TTN | c.55645A>G p.T18549A (on ENST00000591111; = p.T11125A on NM_003319.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | PolyPhen benign (0.053); catalogued as COSV100627907; called by muse, mutect2, varscan2
- UACA | c.2933A>C p.Q978P | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100537727; called by muse, mutect2, varscan2
- UPF2 | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.098); catalogued as COSV100707434; called by muse, mutect2, varscan2
- WDR33 | c.1584C>G p.D528E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); catalogued as rs1553472247, COSV100460619; called by muse, mutect2, varscan2
- WIPF1 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99769361; called by muse, mutect2, varscan2
- YOD1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100263246; called by muse, mutect2, varscan2
- YY1 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99216987; called by muse, mutect2, varscan2
- ZFAND4 | c.2009G>T p.C670F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100763097; called by muse, mutect2, varscan2
- ZFP37 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT tolerated (0.62); PolyPhen benign (0.125); catalogued as COSV100953327; called by muse, mutect2, varscan2
- ZNF449 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100203059; called by muse, mutect2, varscan2
- ZNF479 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100483035, COSV58641325, COSV58642895; called by muse, mutect2, varscan2
- ZNF550 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs1464352274, COSV100286790; called by muse, mutect2, varscan2
- ZNF572 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs200991389, COSV60001650; called by muse, mutect2, varscan2
- ZNF589 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.134); catalogued as rs564454039, COSV61220261, COSV61220407; called by muse, mutect2, varscan2
- ZNF615 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV100943949; called by muse, mutect2, varscan2
- ZNF616 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100348583; called by muse, mutect2, varscan2
- ZNF800 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1031273392, COSV99758182; called by muse, mutect2, varscan2
- ZNF81 | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.406); catalogued as COSV100096166; called by muse, mutect2, varscan2
- ZNF92 | c.1561T>C p.S521P (on ENST00000328747 / NM_152626.4; = p.S452P on NM_007139.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV100165956; called by muse, mutect2, varscan2
- ZNFX1 | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100871000; called by muse, mutect2, varscan2
- ATP1A1 | c.1508_1529del p.H503Pfs*6 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- BMS1 | c.2997del p.S1000Vfs*3 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- C16orf92 | c.106_108del p.V36del | In Frame Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- FAM210A | c.792dup p.V265Sfs*4 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, pindel
- FMN1 | c.3370C>T p.P1124S (on ENST00000616417 / NM_001277313.2; = p.P901S on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LEMD3 | c.1314_1334del p.N439_K445del | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- LRPPRC | c.3654_3662del p.A1219_L1221del | In Frame Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- NUCB2 | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- PSMC5 | c.993_1001del p.I331_R334delinsM | In Frame Del (DEL) | VAF 37/200 reads (19%) | called by mutect2, pindel*, varscan2*
- RETREG1 | c.738del p.K247Sfs*5 (on ENST00000306320 / NM_001034850.2; = p.K106Sfs*5 on NM_019000.4) | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- AAR2 | c.123C>T p.V41= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs200907454, COSV100299417; called by muse, mutect2, varscan2
- ABCA3 | c.4407C>T p.D1469= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs374931466, COSV100069075; called by muse, mutect2, varscan2
- AGFG2 | c.1410C>T p.F470= | Silent (SNP) | VAF 137/355 reads (39%) | catalogued as rs558606792, COSV53544777; called by muse, mutect2, varscan2
- ARMC6 | c.1505G>A p.*502= (on ENST00000392336; = p.*477= on NM_033415.4) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99523156; called by muse, mutect2, varscan2
- ATP2B3 | c.642G>C p.G214= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV54846608, COSV99685736; called by muse, mutect2, varscan2
- C8orf34 | c.1599G>A p.L533= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV100447810; called by muse, mutect2
- CEP250 | c.4326A>G p.G1442= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100699164; called by muse, mutect2, varscan2
- CSMD3 | c.10950T>C p.Y3650= (on ENST00000297405 / NM_001363185.1; = p.Y3481= on NM_052900.3) | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV52339881, COSV99846335; called by muse, mutect2, varscan2
- CSMD3 | c.897T>G p.G299= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99846339; called by muse, mutect2, varscan2
- DCBLD1 | c.1608T>C p.D536= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99758040; called by muse, mutect2, varscan2
- DDHD2 | c.1095A>G p.K365= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV101240783; called by muse, mutect2, varscan2
- DHX58 | c.1938G>T p.R646= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV52425441, COSV99288473; called by muse, mutect2
- DLGAP2 | c.1884G>A p.S628= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs373089965, COSV70096502; called by muse, mutect2, varscan2
- DMP1 | c.840C>T p.S280= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs759841451, COSV56819392; called by muse, mutect2, varscan2
- EPC1 | c.2052G>A p.V684= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99553404; called by muse, mutect2, varscan2
- FAM135B | c.3378C>T p.F1126= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs267601784, COSV52745765; called by muse, mutect2, varscan2
- FAT2 | c.12492G>A p.K4164= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99944015; called by muse, mutect2, varscan2
- FMN2 | c.2259G>T p.G753= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100146986; called by muse, mutect2, varscan2
- GIMAP6 | c.300G>T p.L100= | Silent (SNP) | VAF 51/75 reads (68%) | catalogued as COSV100188378; called by muse, mutect2, varscan2
- GUCY1A1 | c.1002G>A p.T334= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1049509, COSV56654518, COSV99638573; called by muse, mutect2, varscan2
- HAS1 | c.522G>A p.A174= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99708582; called by muse, varscan2
- HPX | c.1122C>T p.I374= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV56418515; called by muse, mutect2, varscan2
- IGF1R | c.2277C>T p.A759= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs754252753, COSV99161558; called by muse, mutect2, varscan2
- JMJD1C | c.4518T>C p.A1506= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100550809; called by muse, mutect2, varscan2
- KCNJ12 | c.1194C>G p.G398= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100056034; called by muse, mutect2, varscan2
- KIF13B | c.3765C>G p.V1255= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV101580790; called by muse, mutect2, varscan2
- KIF21A | c.3657T>G p.S1219= (on ENST00000361418 / NM_001378440.1; = p.S1206= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100735623; called by muse, varscan2
- LEPR | c.2928C>T p.D976= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs138826362; called by muse, mutect2, varscan2
- LNX1 | c.984C>T p.N328= (on ENST00000263925 / NM_001126328.3; = p.N232= on NM_032622.2) | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs752450046, COSV99820531; called by muse, mutect2, varscan2
- NAT9 | c.363C>T p.G121= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99380263; called by muse, mutect2, varscan2
- NAV1 | c.1803T>C p.T601= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99819597; called by muse, mutect2, varscan2
- NEUROD1 | c.12G>A p.S4= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV54549558; called by muse, mutect2, varscan2
- NIPSNAP3A | c.318T>C p.D106= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV101046480; called by muse, varscan2
- NLGN2 | c.1932G>A p.P644= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs114377334; called by muse, varscan2
- NOX4 | c.1623A>T p.T541= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99631756; called by muse, mutect2, varscan2
- NSFL1C | c.336G>A p.K112= | Silent (SNP) | VAF 90/495 reads (18%) | catalogued as COSV99401601; called by muse, mutect2, varscan2
- NTN5 | c.1470G>A p.*490= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99539565; called by muse, mutect2, varscan2
- NUP205 | c.744C>T p.L248= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV99607539; called by muse, mutect2, varscan2
- OR2L13 | c.834C>G p.T278= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100813881; called by muse, mutect2, varscan2
- P2RX1 | c.1002C>T p.T334= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99844924; called by mutect2, varscan2
- PCDHGB1 | c.147C>T p.A49= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99539936, COSV99546083; called by muse, mutect2, varscan2
- PCLO | c.6765T>C p.G2255= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100437167, COSV100438430; called by muse, mutect2, varscan2
- PGAM4 | c.764G>A p.*255= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100431621; called by muse, mutect2, varscan2
- PKHD1L1 | c.2139T>C p.R713= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101006759; called by muse, mutect2, varscan2
- PNMA8B | c.1026G>C p.S342= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV100885517, COSV66536450; called by muse, mutect2, varscan2
- POU4F2 | c.1029G>A p.A343= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs370767940, COSV99850807; called by muse, mutect2, varscan2
- PPP2R2C | c.972C>T p.Y324= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100160840; called by muse, mutect2, varscan2
- PRUNE2 | c.3210C>T p.D1070= | Silent (SNP) | VAF 50/75 reads (67%) | catalogued as rs1377099103, COSV65043919; called by muse, mutect2, varscan2
- RBSN | c.1992C>T p.F664= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs373403772; called by muse, mutect2, varscan2
- REM1 | c.21G>A p.Q7= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as rs968321558, COSV99147784; called by muse, mutect2, varscan2
- RTL5 | c.591C>T p.G197= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV65452429; called by muse, mutect2, varscan2
- SBK1 | c.375C>A p.V125= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100543673; called by muse, mutect2, varscan2
- SLC35A1 | c.906T>C p.G302= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as rs1440632778, COSV101057447; called by muse, mutect2, varscan2
- SLC9B2 | c.606C>T p.G202= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs376080494, COSV60018890; called by muse, mutect2, varscan2
- SMARCC2 | c.1839G>A p.L613= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99911878; called by muse, mutect2, varscan2
- SMOC2 | c.990C>T p.D330= (on ENST00000356284 / NM_001166412.2; = p.D341= on NM_022138.3) | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- STARD3NL | c.684G>A p.E228= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV50519156, COSV99151608; called by mutect2, varscan2
- STON1-GTF2A1L | c.2325G>C p.P775= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100561474, COSV100562256; called by muse, mutect2, varscan2
- STT3A | c.876A>G p.P292= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1018557009, COSV67064769; ClinVar: likely benign; called by mutect2, varscan2
- SVIL | c.3486C>T p.T1162= (on ENST00000355867 / NM_021738.3; = p.T736= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs1474988764, COSV100881518; called by muse, mutect2, varscan2
- TEX15 | c.1761C>T p.P587= (on ENST00000256246; = p.P970= on NM_001350162.2) | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV99822042; called by muse, mutect2, varscan2
- TICAM1 | c.1914T>C p.A638= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99941268; called by muse, mutect2, varscan2
- TIMM17A | c.12C>T p.Y4= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs373964439; called by muse, mutect2, varscan2
- TRIM72 | c.1335G>T p.L445= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100438749; called by muse, mutect2
- TRIML2 | c.681T>G p.A227= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100456330; called by muse, mutect2, varscan2
- TRIO | c.5475G>A p.P1825= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1328891509, COSV100710899; called by muse, mutect2
- TTN | c.54459A>G p.R18153= (on ENST00000591111; = p.R10729= on NM_003319.4) | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100627910; called by muse, mutect2, varscan2
- TUBA3C | c.354C>G p.V118= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV101262837; called by muse, mutect2, varscan2
- UBE2V2 | c.384C>T p.S128= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101568650; called by muse, mutect2, varscan2
- VAT1L | c.321T>C p.S107= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV100214102; called by muse, mutect2, varscan2
- VPS13A | c.201T>G p.L67= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100653423; called by muse, mutect2
- VPS13C | c.4314G>A p.L1438= (on ENST00000644861 / NM_020821.3; = p.L1395= on NM_017684.5) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99830045; called by muse, mutect2, varscan2
- WASHC4 | c.1962G>A p.E654= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1360121188, COSV100162741; called by muse, mutect2, varscan2
- ZNF132 | c.876G>A p.V292= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99571333; called by muse, mutect2, varscan2
- ZNF26 | c.1338A>G p.R446= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- ZNF581 | c.114C>A p.S38= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99552995, COSV99553272; called by muse, mutect2
- ZNF71 | c.810C>T p.Y270= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs765187724, COSV60147224; called by muse, mutect2, varscan2
- ZNRF4 | c.468C>T p.G156= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs374844845; called by muse, mutect2, varscan2
- DSCR4 | n.362C>T | RNA (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100077574; called by muse, mutect2, varscan2
- SLC17A4 | c.*2C>A | 3'UTR (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99766106; called by muse, mutect2, varscan2
- TUSC3 | c.1028+115C>T | Intron (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
